Somatic mutation profile of tumor specimen TCGA-QS-A8F1-01A (aliquot TCGA-QS-A8F1-01A-21D-A37N-09) from TCGA case TCGA-QS-A8F1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 85.9 years (31,386 days).
Specimen TCGA-QS-A8F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 405b3439-fd15-4663-ae43-3288e3ba5c73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QS-A8F1-10A (Blood Derived Normal), aliquot TCGA-QS-A8F1-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/635e93d3-29a8-4081-861e-c481f11f4acd

The open-access MAF lists 68 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 14, Nonsense Mutation 4, In Frame Del 1, Splice Site 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- TP53 | c.247dup p.A83Gfs*66 | Frame Shift Ins (INS) | VAF 33/52 reads (63%) | catalogued as rs867725248, COSV53064565; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABHD5 | c.802A>G p.M268V (on ENST00000458276 / NM_001365650.1; = p.Y330C on NM_016006.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as COSV101369691; called by muse, mutect2
- AHNAK2 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs767475413, COSV100318506; called by muse, mutect2, varscan2
- AMOTL1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100133888; called by muse, mutect2, varscan2
- APOE | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99376218; called by muse, mutect2
- ARID4B | c.3151C>G p.L1051V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); catalogued as COSV99936085; called by muse, mutect2, varscan2
- ATP11A | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as rs1425060161, COSV52121151, COSV52125601; called by muse, mutect2, varscan2
- BSN | c.6323T>C p.M2108T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs747943722, COSV99609427; called by muse, mutect2, varscan2
- CATSPERE | c.2159A>G p.H720R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100835295; called by muse, mutect2, varscan2
- CYP2D6 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs750332098, COSV100637355; called by muse, mutect2, varscan2
- DUSP9 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs782043003, COSV100720149; called by muse, mutect2, varscan2
- FGFR2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs773245022, COSV60642710; called by muse, mutect2, varscan2
- IRX4 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs773654267, COSV51471361; called by muse, mutect2, varscan2
- KIAA0408 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as COSV100847016, COSV64107131; called by mutect2, varscan2
- KMT2C | c.8737G>T p.G2913* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100075015; called by muse, mutect2, varscan2
- LAMA1 | c.7610G>A p.R2537H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs372523357; called by muse, mutect2, varscan2
- LARP1B | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99218715; called by muse, mutect2
- LSG1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1352191497, COSV99503436; called by muse, mutect2, varscan2
- MOXD1 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.17); catalogued as COSV100381798; called by muse, mutect2, varscan2
- MTCH1 | c.1060A>G p.K354E (on ENST00000373627 / NM_001271641.1; = p.K337E on NM_014341.2) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.119); catalogued as COSV101010197; called by muse, mutect2, varscan2
- MUC4 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.234); catalogued as rs373861956; called by muse, mutect2, varscan2
- NPBWR1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58696681; called by muse, mutect2, varscan2
- OR1S2 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224333; called by muse, varscan2
- PEX5L | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as COSV55851835; called by muse, mutect2, varscan2
- PHF20L1 | c.1321A>C p.K441Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99621779; called by muse, mutect2
- PRR16 | c.845C>T p.T282I (on ENST00000407149 / NM_001300783.2; = p.T259I on NM_016644.2) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV101087665; called by muse, mutect2, varscan2
- PTPRS | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV99511827; called by muse, mutect2, varscan2
- RAPH1 | c.1447A>G p.K483E (on ENST00000319170 / NM_213589.3; = p.K535E on NM_203365.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99864251; called by muse, mutect2, varscan2
- RELB | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 74/82 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs374893001; called by muse, mutect2, varscan2
- RPS19 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99702715; called by muse, mutect2, varscan2
- RTTN | c.5290G>A p.V1764M | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs202231574, COSV99733395; called by muse, mutect2, varscan2
- RUNDC3B | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.856); catalogued as rs1206199075, COSV99713873; called by muse, mutect2, varscan2
- SERPING1 | c.872A>C p.N291T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99558105; called by muse, mutect2, varscan2
- SH3RF1 | c.1347-2A>G p.X449_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99499342; called by muse, mutect2, varscan2
- SLC26A8 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as rs772520541, COSV62885581, COSV62885594; called by muse, mutect2, varscan2
- SNX1 | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99976351; called by muse, mutect2, varscan2
- SPOP | c.140A>C p.E47A | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV61653279; called by muse, mutect2, varscan2
- SRI | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs755686986, COSV56000965; called by muse, mutect2, varscan2
- ST18 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1251747128, COSV99390645; called by muse, mutect2, varscan2
- SVIL | c.2608C>G p.P870A (on ENST00000355867 / NM_021738.3; = p.P444A on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100881450, COSV63441591; called by muse, mutect2, varscan2
- TAF10 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); catalogued as rs767511440, COSV100196560; called by mutect2, varscan2
- TCEAL9 | c.180A>G p.I60M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65489030; called by muse, mutect2, varscan2
- TRAK1 | c.1108C>T p.P370S (on ENST00000327628 / NM_001349247.2; = p.P312S on NM_014965.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV58258112; called by muse, mutect2, varscan2
- USP51 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101540686; called by muse, mutect2, varscan2
- ZNF17 | c.1889G>C p.R630T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100300135, COSV56920928; called by muse, mutect2, varscan2
- ZNF512 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1325871846, COSV100820915; called by mutect2, varscan2
- ZNF551 | c.1469T>G p.L490R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99990190; called by muse, mutect2
- ZNF638 | c.3279C>G p.D1093E | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100039531; called by muse, mutect2
- ZNF710 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99184089; called by muse, mutect2
- ZP3 | c.1039G>C p.A347P (on ENST00000394857 / NM_001110354.2; = p.A296P on NM_007155.6) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1183221118, COSV100334643; called by muse, mutect2, varscan2
- CXorf56 | c.229_230del p.M77Vfs*49 (on ENST00000536133 / NM_001170570.2; = p.M77Vfs*6 on NM_022101.4) | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- RPL14 | c.575_592del p.P192_G197del | In Frame Del (DEL) | VAF 28/57 reads (49%) | called by mutect2, pindel, varscan2
- AP3M2 | c.771C>T p.F257= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1295343281, COSV99441836; called by muse, mutect2, varscan2
- CNST | c.672C>A p.L224= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100829777, COSV100829901; called by muse, mutect2, varscan2
- COL9A3 | c.1134C>T p.R378= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs138208105; called by muse, mutect2, varscan2
- FAM13A | c.420C>A p.L140= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV52010082, COSV99984414; called by muse, mutect2, varscan2
- FER1L6 | c.1029G>A p.L343= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1425163331, COSV101206110; called by muse, mutect2, varscan2
- FZD3 | c.1866G>A p.R622= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99528315; called by muse, mutect2, varscan2
- KCNH8 | c.2127T>A p.I709= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV60459219; called by muse, mutect2, varscan2
- MCF2 | c.1833C>T p.F611= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100644998; called by muse, mutect2
- OR4D1 | c.417A>G p.Q139= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1283178415, COSV99274256; called by muse, mutect2, varscan2
- RAD50 | c.3300T>C p.A1100= | Silent (SNP) | VAF 52/58 reads (90%) | catalogued as COSV99529377; called by muse, mutect2, varscan2
- RGS12 | c.2703G>A p.S901= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs138222443; called by muse, mutect2, varscan2
- SCRIB | c.3057C>T p.V1019= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs782071220, COSV100253886; called by muse, mutect2, varscan2
- SH3TC1 | c.3798C>T p.A1266= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs773649467, COSV99795161; called by muse, mutect2, varscan2
- TNIK | c.3894C>G p.G1298= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV52677309, COSV99458849; called by muse, mutect2, varscan2
- GNA12 | c.526-29327G>A | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99282911; called by muse, mutect2, varscan2
